Somatic mutation profile of tumor specimen TCGA-AB-2874-03A (aliquot TCGA-AB-2874-03A-01W-0732-08) from TCGA case TCGA-AB-2874, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,764 days).
Specimen TCGA-AB-2874-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d876fc44-dc33-4f12-9df5-0ea7f6bc874c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2874-11A (Solid Tissue Normal), aliquot TCGA-AB-2874-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e090f93f-b8f9-41b3-9007-17bf9519777b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AURKC | c.424C>T p.R142C (on ENST00000302804 / NM_001015878.2; = p.R108C on NM_003160.3) | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs757093824, COSV57138081; called by muse, mutect2, varscan2
- CEBPA | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57197204, COSV57198461; called by muse, mutect2, varscan2
- GREM2 | c.72C>A p.N24K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV58950266; called by muse, varscan2
